Gene-level copy-number profile of tumor specimen TCGA-YU-A90V-01A from TCGA case TCGA-YU-A90V, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 42.9 years (15,663 days).
Specimen TCGA-YU-A90V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 52e88165-676e-45db-a7b9-3386befd567e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-YU-A90V-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,741 have no estimate.
https://portal.gdc.cancer.gov/files/8ad7d836-302f-4505-a44b-521f9d2433c8

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,069; copy number 2: 17,921; copy number 3: 27,974; copy number 4: 8,248; copy number 5: 1,131; copy number 6: 196; copy number 7: 238; copy number 8: 510; copy number 9: 183; copy number 10: 143; copy number 11: 62; copy number 12: 28; copy number 13: 37; copy number 15: 9; copy number 17: 2; copy number 24: 9; copy number 25: 1; copy number 35: 15; copy number 40: 6; copy number 42: 26; copy number 52: 3; copy number 62: 20; copy number 64: 11; copy number 72: 2; copy number 79: 16; copy number 82: 22.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,343 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:144,421,386–144,560,829, 6 genes, copy number 7: NBPF15, PFN1P6, AC246785.1, RNVU1-26, RNVU1-2A, RNVU1-28.
- chr6:42,890,265–45,377,953, 86 genes, copy number 8–9 (within-gene range 5–9) (broad region; genes not listed).
- chr7:63,888,200–80,391,474, 380 genes, copy number 8–10 (within-gene range 5–10) (broad region; genes not listed).
- chr7:80,377,554–80,377,835, 1 gene, copy number 8 (within-gene range 5–8): SNRPBP1.
- chr12:66,767–41,072,415, 870 genes, copy number 7–82 (within-gene range 4–82) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,557. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
